Gene-level copy-number profile of tumor specimen ALCH-B06A-TTP1-A from ALCHEMIST case ALCH-B06A, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.7 years (27,634 days).
Specimen ALCH-B06A-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7d7d8d43-5ffc-4b55-9912-b2902f146b55.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B06A-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/9c01246b-9e24-424a-a97c-4433fa818781

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 546; copy number 1: 6,464; copy number 2: 48,847; copy number 3: 2,931; copy number 4: 98; copy number 5: 4; copy number 6: 4; copy number 7: 4; copy number 8: 1; copy number 18: 1; copy number 26: 1.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:178,113,532–178,126,081, 1 gene: N4BP3.
- chr7:63,632,608–63,771,047, 3 genes: AC006015.1, AC079355.1, CICP24.
- chr9:61,665,579–61,666,386, 1 gene: AL935212.2.
- chr9:61,898,805–61,911,022, 1 gene: FAM242E.
- chr9:66,721,158–66,745,929, 3 genes: ATP5F1AP10, SDR42E1P4, FKBP4P8.
- chr9:66,942,703–67,329,404, 11 genes: AL353770.4, AL353770.2, FAM74A3, AL353770.3, AL353770.1, SPATA31A3, CNTNAP3P2, RN7SL422P, AL162233.1, RBM17P2, BX005195.1.
- chr9:136,992,422–136,993,984, 1 gene: PAXX.
- chr9:137,174,784–137,188,560, 1 gene: ANAPC2.
- chr11:70,862,790–70,872,368, 2 genes (within-gene range 0–1): SHANK2-AS3, MIR3664.
- chr11:71,428,193–71,452,868, 2 genes: DHCR7, AP002387.1.
- chr11:71,473,503–71,473,568, 1 gene (within-gene range 0–1): MIR6754.
- chr16:89,711,856–89,740,925, 2 genes (within-gene range 0–1): VPS9D1-AS1, ZNF276.
- chr16:90,105,095–90,106,316, 1 gene (within-gene range 0–2): AC133919.1.
- chr17:2,724,411–2,749,504, 3 genes: CCDC92B, MIR1253, hsa-mir-1253.
- chr19:1,038,727–1,039,064, 1 gene (within-gene range 0–2): AC011558.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:136,848,724–136,860,799, 2 genes, copy number 5 (within-gene range 1–5): PHPT1, MAMDC4.
- chr9:136,969,243–136,986,410, 4 genes, copy number 5–7: LINC02692, PTGDS, AL807752.7, LCNL1.
- chr9:137,191,617–137,204,193, 1 gene, copy number 7 (within-gene range 2–7): TPRN.
- chr9:137,220,247–137,221,581, 1 gene, copy number 18: RNF208.
- chr19:1,228,287–1,239,522, 2 genes, copy number 8–26 (within-gene range 2–26): CBARP, AC004221.1.
- chr19:1,248,553–1,279,244, 4 genes, copy number 6: MIDN, CIRBP, CIRBP-AS1, FAM174C.
- chr19:1,481,428–1,490,752, 1 gene, copy number 5 (within-gene range 3–5): PCSK4.

Autosomal genes at a single copy (total copy number 1): 4,248. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
